Gene-level copy-number profile of tumor specimen TCGA-DD-AADM-01A from TCGA case TCGA-DD-AADM, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.5 years (21,349 days).
Specimen TCGA-DD-AADM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.2b77ec58-4082-44e0-a03f-8fd2f7d6ac64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9a93998-c317-40cb-8af9-23a8c80eaa07

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,471; copy number 3: 5,737; copy number 4: 38,542; copy number 5: 775; copy number 6: 2,998; copy number 7: 1,790; copy number 8: 4,846; copy number 9: 586; copy number 10: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADM-01A-11D-A40Q-01): tumor purity 0.79, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 661 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,111,121–164,980,137, 23 genes, copy number 9 (within-gene range 8–9): RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2, AL603841.1, RNA5SP62, RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:207,909,992–216,423,448, 145 genes, copy number 9–10 (broad region; genes not listed).
- chr1:237,555,040–241,357,230, 53 genes, copy number 10 (within-gene range 8–10): AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr5:83,531,352–85,849,199, 24 genes, copy number 9 (within-gene range 4–9): VCAN-AS1, HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1, EDIL3, RNU6-448P, EDIL3-DT, PPIAP79, AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1, AC010486.1, AC010486.2, AC010486.3, RPL5P17, AC026700.1, AC010595.1, RPS2P25, AC026414.1.
- chr5:103,548,855–105,392,970, 11 genes, copy number 9: NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1.
- chr5:163,855,140–168,264,157, 26 genes, copy number 9 (within-gene range 8–9): AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.
- chr8:104,590,733–105,804,539, 1 gene, copy number 9 (within-gene range 8–9): ZFPM2.
- chr8:105,142,860–139,463,016, 378 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
